TCGA case TCGA-4V-A9QM — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus; Tissue source site: Hospital Louis Pradel. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0be4fa90-0122-4b26-b35f-7b1a4a16e63b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 39 years; Vital status: Alive.

Diagnoses (1)
1. Thymoma, type AB, malignant: ICD-O-3 morphology code: 8582/3; ICD-10 code: C37; Tissue or organ of origin: Thymus; Site of resection or biopsy: Thymus; Classification of tumor: primary; Age at diagnosis: 39.9 years (14,576 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; Masaoka stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,253 days (3.4 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,171 days (3.2 years); Disease response: Tumor Free.
- Days to follow up: 1,253 days (3.4 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 169 cm; BMI: 23.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-4V-A9QM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 90 mg.
  Slide TCGA-4V-A9QM-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-4V-A9QM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-4V-A9QM-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 140 mg.
  Slide TCGA-4V-A9QM-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Stage record: Masaoka stage: I.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type AB.
- Primary pathology: Method initial path diagnosis: Median Sternectomy; History myasthenia gravis: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,253 days; disease-specific survival: no event (censored), 1,253 days; progression-free interval: no event (censored), 1,253 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-4V-A9QM-01A-11D-A422-01): tumor purity 0.34, ploidy 2, whole-genome doublings 0.
